Somatic mutation profile of tumor specimen TCGA-EM-A2CP-01A (aliquot TCGA-EM-A2CP-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 26.7 years (9,759 days).
Specimen TCGA-EM-A2CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f247183d-bbea-49ed-9cbd-ed661eec871e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CP-10A (Blood Derived Normal), aliquot TCGA-EM-A2CP-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f71d5090-5dce-4fb2-9987-d261716f3c17

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRC32 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs753703404, COSV52633523; called by mutect2, varscan2
- PRRG3 | c.573C>T p.P191= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1243229492, COSV64851172; called by muse, mutect2
